Gene-level copy-number profile of tumor specimen C3L-04537-01 from CPTAC case C3L-04537, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 51.4 years (18,762 days).
Specimen C3L-04537-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 327e3b1c-2e95-45cd-9ff7-d21f7ce267fe.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-04537-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/f9a7ade4-6fa2-42b0-b15f-b2c8dad6457c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 65; copy number 1: 5,878; copy number 2: 47,707; copy number 3: 5,089; copy number 4: 15; copy number 24: 76; copy number 25: 21; copy number 26: 2; copy number 31: 43; copy number 54: 19.

Homozygous deletions (total copy number 0; autosomes only): 65 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,331,446–22,214,672, 65 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 161 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:203,400,266–204,728,106, 43 genes, copy number 31: LARP7P1, PRELP, OPTC, ATP2B4, NSA2P1, SNORA77, LAX1, ZC3H11A, ZBED6, AC114402.2, AC114402.1, RPL35AP5, SNRPE, KRT8P29, HSPE1P6, CBX1P3, LINC00303, AL592146.2, SOX13, AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2, AL161793.1, RNA5SP75, AL161793.2.
- chr4:51,993,702–57,724,655, 118 genes, copy number 24–54 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,031. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
